Somatic mutation profile of tumor specimen TCGA-3Q-A9WF-01A (aliquot TCGA-3Q-A9WF-01A-11D-A423-09) from TCGA case TCGA-3Q-A9WF, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 71.5 years (26,117 days).
Specimen TCGA-3Q-A9WF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7174f16-0c45-4b74-9fab-cf7aa7cde953.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3Q-A9WF-10A (Blood Derived Normal), aliquot TCGA-3Q-A9WF-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81b2f84c-29b0-4539-9005-5a888091bfa1

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV65450888, COSV65451589; called by muse, mutect2
- TRH | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2
